Somatic mutation profile of tumor specimen TCGA-MH-A55Z-01A (aliquot TCGA-MH-A55Z-01A-11D-A26P-10) from TCGA case TCGA-MH-A55Z, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 65.8 years (24,017 days).
Specimen TCGA-MH-A55Z-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fefbe650-9dc0-4312-80c1-0c21e970b649.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-MH-A55Z-10A (Blood Derived Normal), aliquot TCGA-MH-A55Z-10A-01D-A26P-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4f46f12f-2a19-402a-8cae-0940c3bec322

The open-access MAF lists 106 somatic variants for this specimen: 74 protein-altering or splice-affecting, 26 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 58, Silent 26, Nonsense Mutation 6, Frame Shift Del 5, 3'UTR 3, Intron 2, Splice Region 1, Frame Shift Ins 1, RNA 1, In Frame Ins 1, Splice Site 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC5 | c.2866C>G p.L956V | Missense Mutation (SNP) | VAF 37/64 reads (58%) | SIFT tolerated (0.06); PolyPhen benign (0.387); catalogued as rs975692997, COSV55588850; called by muse, mutect2, varscan2
- ADD1 | c.1724A>G p.Y575C | Missense Mutation (SNP) | VAF 86/190 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV53268049; called by muse, mutect2
- ALDH1B1 | c.1324T>C p.Y442H | Missense Mutation (SNP) | VAF 47/132 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66619536; called by muse, mutect2, varscan2
- APOBEC1 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 49/199 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.879); catalogued as COSV57548610; called by muse, mutect2, varscan2
- ARMT1 | c.1315G>A p.G439S | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT tolerated (0.22); PolyPhen benign (0.028); catalogued as COSV66178471; called by muse, mutect2, varscan2
- ATP1A1 | c.2219A>G p.D740G | Missense Mutation (SNP) | VAF 54/140 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55190716; called by muse, mutect2, varscan2
- BID | c.298T>C p.Y100H (on ENST00000317361 / NM_197966.2; = p.Y54H on NM_001196.4) | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as COSV58006562; called by muse, mutect2
- BTC | c.74T>G p.I25S | Missense Mutation (SNP) | VAF 52/143 reads (36%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.571); catalogued as COSV67547484; called by muse, mutect2, varscan2
- C12orf57 | c.143G>T p.G48V | Missense Mutation (SNP) | VAF 110/186 reads (59%) | SIFT tolerated (0.6); PolyPhen benign (0.013); catalogued as COSV57546657; called by muse, mutect2, varscan2
- C2orf16 | c.2333A>T p.E778V | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.481); catalogued as COSV62674891; called by muse, mutect2, varscan2
- C4orf17 | c.56T>C p.I19T | Missense Mutation (SNP) | VAF 59/136 reads (43%) | SIFT tolerated (0.38); PolyPhen benign (0.058); catalogued as COSV58511779; called by muse, mutect2, varscan2
- C9orf50 | c.850A>G p.T284A | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs763685959, COSV65252322; called by muse, mutect2, varscan2
- CCDC191 | c.2496T>G p.F832L | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1439778925, COSV55671370; called by muse, mutect2, varscan2
- CHEK1 | c.96A>C p.E32D | Missense Mutation (SNP) | VAF 31/65 reads (48%) | SIFT tolerated (0.38); PolyPhen benign (0.092); catalogued as COSV54022877; called by muse, mutect2, varscan2
- COPS2 | c.1075C>T p.L359F | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV54644902; called by muse, mutect2, varscan2
- CRACD | c.3067G>A p.E1023K | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.037); catalogued as COSV51718949; called by muse, mutect2, varscan2
- CSPP1 | c.3758C>T p.T1253I (on ENST00000676605; = p.T1212I on NM_024790.6) | Missense Mutation (SNP) | VAF 76/237 reads (32%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.811); catalogued as COSV51582724; called by muse, mutect2, varscan2
- CYP2A13 | c.940T>G p.F314V | Missense Mutation (SNP) | VAF 43/107 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as COSV57837129; called by muse, mutect2, varscan2
- DCAF13 | c.766G>T p.A256S | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0.15); catalogued as COSV52571313; called by muse, mutect2, varscan2
- DNMT3A | c.1226G>A p.W409* | Nonsense Mutation (SNP) | VAF 43/102 reads (42%) | catalogued as COSV53047172, COSV53062861; called by muse, mutect2, varscan2
- EXPH5 | c.5695G>A p.E1899K | Missense Mutation (SNP) | VAF 39/118 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV56200833; called by muse, mutect2, varscan2
- FAM110C | c.698G>A p.G233E | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV59655869; called by muse, mutect2, varscan2
- FER1L5 | c.3382A>T p.I1128F (on ENST00000623019; = p.I1101F on NM_001293083.2) | Missense Mutation (SNP) | VAF 34/84 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.711); catalogued as COSV67605965; called by muse, mutect2
- GAK | c.1106A>T p.Q369L | Missense Mutation (SNP) | VAF 26/57 reads (46%) | SIFT deleterious (0.05); PolyPhen benign (0.4); catalogued as COSV58503906; called by muse, mutect2, varscan2
- GNL2 | c.1244G>C p.W415S | Missense Mutation (SNP) | VAF 41/84 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV66080061; called by muse, mutect2, varscan2
- GPC6 | c.210A>T p.E70D | Missense Mutation (SNP) | VAF 38/87 reads (44%) | SIFT tolerated (0.13); PolyPhen benign (0.101); catalogued as rs1389664856, COSV65506482; called by muse, mutect2, varscan2
- GRB10 | c.1774G>A p.V592M (on ENST00000398812; = p.V546M on NM_001001549.3) | Missense Mutation (SNP) | VAF 68/291 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.471); catalogued as COSV60009338; called by muse, mutect2, varscan2
- KIF21A | c.3944A>G p.H1315R (on ENST00000361418 / NM_001378440.1; = p.H1302R on NM_017641.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 274/492 reads (56%) | SIFT tolerated (0.63); PolyPhen benign (0.045); catalogued as COSV62769785; called by muse, varscan2
- KRTAP10-11 | c.43G>A p.D15N | Missense Mutation (SNP) | VAF 33/86 reads (38%) | SIFT tolerated (0.57); PolyPhen benign (0.129); catalogued as rs371095766; called by muse, mutect2, varscan2
- LCP2 | c.1234G>A p.A412T | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs770608317, COSV50448581; called by muse, mutect2, varscan2
- LPAR4 | c.350C>A p.A117E | Missense Mutation (SNP) | VAF 85/102 reads (83%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); catalogued as COSV70912445; called by muse, mutect2, varscan2
- LTBP3 | c.1548+2T>A p.X516_splice | Splice Site (SNP) | VAF 32/99 reads (32%) | catalogued as COSV57239816; called by muse, mutect2, varscan2
- MPRIP | c.2243G>A p.R748Q | Missense Mutation (SNP) | VAF 155/254 reads (61%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.992); catalogued as rs756832139, COSV57926627; called by muse, mutect2, varscan2
- NDST3 | c.164T>G p.L55R | Missense Mutation (SNP) | VAF 49/156 reads (31%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.148); catalogued as COSV56616738; called by muse, mutect2, varscan2
- NEK9 | c.2356C>T p.R786* | Nonsense Mutation (SNP) | VAF 28/62 reads (45%) | catalogued as rs765160714, COSV53130257; called by muse, mutect2, varscan2
- NFE2L3 | c.1319_1320del p.S440Cfs*3 | Frame Shift Del (DEL) | VAF 34/153 reads (22%) | catalogued as rs780640444; called by pindel, varscan2
- OBSCN | c.8416G>T p.E2806* | Nonsense Mutation (SNP) | VAF 97/207 reads (47%) | catalogued as COSV52761888, COSV99486047; called by muse, mutect2, varscan2
- OGDH | c.1766G>T p.W589L | Missense Mutation (SNP) | VAF 34/153 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56047940; called by muse, mutect2
- OGDH | c.1768C>A p.P590T | Missense Mutation (SNP) | VAF 33/151 reads (22%) | SIFT tolerated (0.23); PolyPhen benign (0.009); catalogued as COSV56047963; called by muse, mutect2
- OR51G2 | c.391A>G p.I131V | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.065); catalogued as COSV58992464; called by muse, mutect2, varscan2
- OR6Y1 | c.716G>A p.R239H | Missense Mutation (SNP) | VAF 78/163 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs770930620, COSV56929021; called by muse, mutect2, varscan2
- PACC1 | c.868C>T p.P290S | Missense Mutation (SNP) | VAF 63/173 reads (36%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.946); catalogued as COSV54787183; called by muse, mutect2, varscan2
- PCNX4 | c.343G>T p.E115* | Nonsense Mutation (SNP) | VAF 28/88 reads (32%) | catalogued as COSV58307557; called by muse, mutect2, varscan2
- POLM | c.863C>T p.T288I | Missense Mutation (SNP) | VAF 36/116 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.403); catalogued as rs931346679, COSV54241961; called by muse, mutect2, varscan2
- PRRC2C | c.2459A>G p.Q820R (on ENST00000367742; = p.Q818R on NM_015172.4) | Missense Mutation (SNP) | VAF 53/133 reads (40%) | SIFT tolerated (0.45); PolyPhen benign (0.142); catalogued as COSV58903716; called by muse, mutect2, varscan2
- RRP12 | c.3886C>T p.R1296* | Nonsense Mutation (SNP) | VAF 26/55 reads (47%) | catalogued as rs371319861; called by muse, mutect2, varscan2
- SIPA1 | c.1022G>A p.R341Q | Missense Mutation (SNP) | VAF 84/180 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.926); catalogued as rs146916012; called by muse, mutect2
- SKAP2 | c.805G>C p.E269Q | Missense Mutation (SNP) | VAF 40/189 reads (21%) | SIFT tolerated (0.31); PolyPhen benign (0.151); catalogued as COSV61722603, COSV61729178; called by muse, mutect2, varscan2
- SLC10A4 | c.800A>C p.K267T | Missense Mutation (SNP) | VAF 66/182 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.673); catalogued as COSV56718452; called by muse, mutect2, varscan2
- SLC23A1 | c.79C>T p.P27S | Missense Mutation (SNP) | VAF 71/158 reads (45%) | SIFT tolerated (0.74); PolyPhen benign (0.028); catalogued as COSV62296282; called by muse, mutect2, varscan2
- SLC35B1 | c.880A>C p.I294L (on ENST00000649906; = p.I257L on NM_005827.4) | Missense Mutation (SNP) | VAF 64/183 reads (35%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.559); catalogued as COSV53602682; called by muse, mutect2, varscan2
- SMARCA4 | c.2971A>G p.K991E | Missense Mutation (SNP) | VAF 31/81 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60791274; called by muse, mutect2, varscan2
- SMARCAL1 | c.973G>A p.A325T | Missense Mutation (SNP) | VAF 92/242 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.127); catalogued as COSV61920619; called by muse, mutect2
- SOGA1 | c.2547G>C p.K849N | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.796); catalogued as COSV52915883; called by muse, mutect2, varscan2
- ST6GAL2 | c.502G>C p.V168L | Missense Mutation (SNP) | VAF 58/151 reads (38%) | PolyPhen benign (0); catalogued as COSV64527568; called by muse, mutect2, varscan2
- SYT13 | c.397C>G p.L133V | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT tolerated (0.29); PolyPhen benign (0.037); catalogued as COSV50073110; called by muse, mutect2, varscan2
- TNFAIP6 | c.781A>T p.T261S | Missense Mutation (SNP) | VAF 38/79 reads (48%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV54640476; called by muse, mutect2, varscan2
- TNPO1 | c.1286T>G p.L429* | Nonsense Mutation (SNP) | VAF 15/72 reads (21%) | catalogued as COSV61521317; called by muse, varscan2
- TRIM25 | c.1828G>C p.A610P | Missense Mutation (SNP) | VAF 107/179 reads (60%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs756810953, COSV57543785; called by muse, mutect2, varscan2
- UBR4 | c.2569C>G p.R857G | Missense Mutation (SNP) | VAF 118/232 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV64386625; called by muse, mutect2, varscan2
- UNC80 | c.3880G>A p.G1294R | Missense Mutation (SNP) | VAF 34/103 reads (33%) | SIFT tolerated (0.27); PolyPhen benign (0.168); catalogued as rs1378037500, COSV55887866, COSV55887990; called by muse, mutect2, varscan2
- WDR17 | c.3100G>C p.V1034L | Missense Mutation (SNP) | VAF 29/72 reads (40%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0); catalogued as COSV54571587; called by muse, mutect2, varscan2
- ZNF135 | c.1520C>T p.S507L (on ENST00000313434 / NM_001289401.2; = p.S519L on NM_003436.4) | Missense Mutation (SNP) | VAF 43/127 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.315); catalogued as rs2228277; called by muse, mutect2, varscan2
- ZNF33B | c.2041A>G p.I681V | Missense Mutation (SNP) | VAF 30/72 reads (42%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as COSV63942236; called by muse, mutect2, varscan2
- ZNF407 | c.2642G>A p.C881Y | Missense Mutation (SNP) | VAF 35/125 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55248819; called by muse, mutect2, varscan2
- ZNF438 | c.2371C>T p.L791F | Missense Mutation (SNP) | VAF 51/135 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV59193925; called by muse, mutect2, varscan2
- ZSCAN12 | c.778G>C p.D260H | Missense Mutation (SNP) | VAF 48/134 reads (36%) | SIFT tolerated (0.23); PolyPhen benign (0.139); catalogued as COSV63010738; called by muse, mutect2, varscan2
- BDNF | c.56_63del p.A19Efs*40 | Frame Shift Del (DEL) | VAF 33/92 reads (36%) | called by mutect2, pindel, varscan2
- CANX | c.652del p.H218Mfs*9 | Frame Shift Del (DEL) | VAF 20/51 reads (39%) | called by mutect2, varscan2
- EHMT2 | c.2917-5C>G | Splice Region (SNP) | VAF 144/359 reads (40%) | called by muse, mutect2, varscan2
- EIF2AK1 | c.1124_1125delinsTACT p.Q375Lfs*5 | Frame Shift Ins (INS) | VAF 20/129 reads (16%) | called by pindel, varscan2*
- MKI67 | c.7961del p.P2654Qfs*4 | Frame Shift Del (DEL) | VAF 42/118 reads (36%) | called by mutect2, pindel, varscan2
- TBCK | c.1088del p.G363Vfs*14 (on ENST00000273980 / NM_001163436.4; = p.G300Vfs*14 on NM_033115.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 14/29 reads (48%) | called by mutect2, pindel, varscan2
- VLDLR | c.602_604dup p.S201dup | In Frame Ins (INS) | VAF 48/125 reads (38%) | called by mutect2, pindel, varscan2
- ADAMTS2 | c.2688C>A p.A896= | Silent (SNP) | VAF 25/76 reads (33%) | catalogued as COSV52371745; called by muse, mutect2, varscan2
- ADCY9 | c.730C>T p.L244= | Silent (SNP) | VAF 50/138 reads (36%) | catalogued as rs1397424735, COSV53574038; called by muse, mutect2, varscan2
- AFAP1L2 | c.51C>T p.F17= | Silent (SNP) | VAF 31/87 reads (36%) | catalogued as COSV58413790; called by muse, mutect2, varscan2
- AKAP17A | c.1599C>T p.P533= | Silent (SNP) | VAF 7/95 reads (7%) | catalogued as rs747336063, COSV100002215, COSV58309183; called by muse, mutect2
- AP4E1 | c.3363T>G p.T1121= | Silent (SNP) | VAF 62/117 reads (53%) | catalogued as COSV55916296; called by muse, mutect2, varscan2
- C2orf81 | c.286C>A p.R96= | Silent (SNP) | VAF 46/110 reads (42%) | catalogued as COSV51763296; called by muse, mutect2, varscan2
- FSTL5 | c.2337A>T p.I779= | Silent (SNP) | VAF 66/140 reads (47%) | catalogued as COSV60188918; called by muse, mutect2, varscan2
- GEMIN6 | c.258C>T p.F86= | Silent (SNP) | VAF 41/117 reads (35%) | catalogued as COSV56140187; called by muse, mutect2, varscan2
- GIGYF2 | c.1323T>A p.P441= | Silent (SNP) | VAF 43/88 reads (49%) | catalogued as COSV65248275; called by muse, mutect2, varscan2
- GJB5 | c.702C>T p.T234= | Silent (SNP) | VAF 133/307 reads (43%) | catalogued as rs1206918234, COSV58355914; called by muse, mutect2, varscan2
- KCNJ13 | c.756T>A p.P252= | Silent (SNP) | VAF 81/188 reads (43%) | catalogued as COSV52084960; called by muse, mutect2, varscan2
- LAMA3 | c.8181T>C p.F2727= (on ENST00000313654 / NM_198129.4; = p.F1118= on NM_000227.6) | Silent (SNP) | VAF 47/128 reads (37%) | catalogued as COSV52533083; called by muse, mutect2, varscan2
- LRFN5 | c.1701C>T p.S567= | Silent (SNP) | VAF 41/110 reads (37%) | catalogued as COSV53251137, COSV99983365; called by muse, mutect2, varscan2
- LYST | c.9357C>T p.L3119= | Silent (SNP) | VAF 27/67 reads (40%) | catalogued as COSV67705786; called by muse, mutect2, varscan2
- MACF1 | c.5382T>C p.A1794= | Silent (SNP) | VAF 83/202 reads (41%) | catalogued as COSV57116351; called by muse, mutect2, varscan2
- MAP2K4 | c.480C>T p.Y160= | Silent (SNP) | VAF 56/200 reads (28%) | catalogued as COSV62256427; called by muse, mutect2, varscan2
- MTMR10 | c.819C>G p.S273= | Silent (SNP) | VAF 36/80 reads (45%) | catalogued as COSV58727818; called by muse, mutect2, varscan2
- NFRKB | c.1521C>T p.D507= (on ENST00000446488 / NM_001143835.2; = p.D532= on NM_006165.3) | Silent (SNP) | VAF 25/68 reads (37%) | catalogued as rs1201013712, COSV58757364; called by muse, mutect2, varscan2
- NPEPL1 | c.891A>C p.A297= | Silent (SNP) | VAF 9/19 reads (47%) | catalogued as COSV61938677; called by muse, mutect2, varscan2
- PLEKHA8 | c.861T>C p.T287= | Silent (SNP) | VAF 127/318 reads (40%) | catalogued as COSV51650018; called by muse, mutect2, varscan2
- PUF60 | c.345A>G p.Q115= | Silent (SNP) | VAF 24/57 reads (42%) | catalogued as COSV57647891; called by muse, mutect2, varscan2
- RRP1B | c.1695C>G p.P565= | Silent (SNP) | VAF 15/29 reads (52%) | catalogued as rs1458381139, COSV61478830; called by muse, mutect2
- RUBCN | c.2328C>T p.F776= | Silent (SNP) | VAF 67/144 reads (47%) | catalogued as COSV56364731; called by muse, mutect2, varscan2
- SLC5A8 | c.513G>A p.V171= | Silent (SNP) | VAF 56/98 reads (57%) | catalogued as COSV65987021; called by muse, mutect2, varscan2
- ZNF407 | c.2643C>T p.C881= | Silent (SNP) | VAF 34/122 reads (28%) | catalogued as COSV55248843; called by muse, mutect2, varscan2
- ZNF638 | c.2289T>C p.T763= | Silent (SNP) | VAF 44/107 reads (41%) | catalogued as COSV52485124; called by muse, mutect2, varscan2
- AC099552.1 | n.309C>G | RNA (SNP) | VAF 117/267 reads (44%) | called by muse, mutect2, varscan2
- CREB3L2 | c.*5_*6del | 3'UTR (DEL) | VAF 56/142 reads (39%) | called by mutect2, varscan2
- DCAF4L1 | c.*651T>C | 3'UTR (SNP) | VAF 26/68 reads (38%) | catalogued as COSV100295557; called by muse, mutect2, varscan2
- MAGEH1 | c.*94del | 3'UTR (DEL) | VAF 45/72 reads (63%) | called by mutect2, pindel, varscan2
- PLEKHA5 | c.2400+1220A>G | Intron (SNP) | VAF 43/155 reads (28%) | called by muse, mutect2, varscan2
- SLC5A10 | c.1242-2061G>C | Intron (SNP) | VAF 80/340 reads (24%) | called by muse, mutect2, varscan2
